Gene-level copy-number profile of specimen HCM-BROD-0206-C25-85A from HCMI case HCM-BROD-0206-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 73.2 years (26,732 days).
Specimen HCM-BROD-0206-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3056e186-cf36-445f-8084-c69d6a1db3f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0206-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/96d8c6c5-1e6c-459c-95be-ea5da4987de6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 669; copy number 2: 32,836; copy number 3: 19,286; copy number 4: 5,445; copy number 5: 118; copy number 6: 5; copy number 7: 11; copy number 8: 2; copy number 15: 32.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 168 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:181,683,113–181,738,715, 4 genes, copy number 5: AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P.
- chr4:38,286,994–38,523,180, 5 genes, copy number 5: AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259.
- chr6:32,517,353–32,530,287, 1 gene, copy number 5: HLA-DRB5.
- chr7:99,756,960–100,140,682, 31 genes, copy number 5–6: CYP3A4, AC069294.1, CYP3A137P, CYP3A43, AC011904.1, CYP3A52P, OR2AE1, TRIM4, GJC3, AC004522.3, Y_RNA, AC004522.1, AZGP1, AC004522.4, AZGP1P1, AC004522.2, ZKSCAN1, ZSCAN21, ZNF3, COPS6, MCM7, MIR25, MIR93, MIR106B, AP4M1, TAF6, AC073842.2, CNPY4, MBLAC1, AC073842.1, RPL7P60.
- chr14:65,197,254–65,335,183, 7 genes, copy number 7: LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708.
- chr18:3,878,058–3,897,069, 3 genes, copy number 5 (within-gene range 4–5): DLGAP1-AS3, MIR6718, RNU6-831P.
- chr19:28,790,812–30,957,192, 38 genes, copy number 7–15: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr19:41,050,449–42,390,297, 79 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 351. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
